Somatic mutation profile of tumor specimen TCGA-86-7713-01A (aliquot TCGA-86-7713-01A-11D-2063-08) from TCGA case TCGA-86-7713, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.6 years (25,791 days).
Specimen TCGA-86-7713-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8a2594c-7c6e-476e-be39-fdc0688e45bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-7713-10A (Blood Derived Normal), aliquot TCGA-86-7713-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cb287d4-4de0-48e9-aa7e-6dac44363360

The open-access MAF lists 167 somatic variants for this specimen: 133 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 31, Nonsense Mutation 10, Frame Shift Del 6, Splice Site 2, Splice Region 2, 5'Flank 1, RNA 1, Intron 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS14 | c.901G>C p.G301R | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64606964; called by muse, mutect2, varscan2
- ADAMTS2 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV51109349; called by muse, mutect2, varscan2
- AFF4 | c.1415G>T p.W472L | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54800305; called by muse, mutect2, varscan2
- AKAP6 | c.4364G>C p.G1455A | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.112); catalogued as COSV55235401; called by muse, mutect2, varscan2
- ARHGAP11A | c.2241C>G p.N747K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV55708742; called by muse, mutect2, varscan2
- ARNT2 | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57591064; called by muse, mutect2, varscan2
- ASNS | c.672A>C p.P224= | Splice Region (SNP) | VAF 14/87 reads (16%) | catalogued as COSV51556499; called by muse, mutect2, varscan2
- ASPM | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54139906; called by muse, mutect2, varscan2
- ASXL3 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV52476275; called by muse, mutect2, varscan2
- BOD1 | c.375G>T p.L125F | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV53633347; called by muse, varscan2
- CBFA2T3 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs751384339, COSV51933593; called by muse, mutect2, varscan2
- CDK8 | c.1010A>T p.E337V | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV67423345; called by muse, mutect2, varscan2
- CKB | c.192G>A p.P64= | Splice Region (SNP) | VAF 5/19 reads (26%) | catalogued as COSV62379735; called by muse, mutect2, varscan2
- COL2A1 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs778135776, CD1513906, COSV61534954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS5 | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV51593384; called by muse, mutect2, varscan2
- CRTAC1 | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV54002635, COSV54010718; called by muse, mutect2, varscan2
- CTR9 | c.507A>C p.K169N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV63729798; called by muse, varscan2
- DCAF6 | c.2030G>T p.R677L (on ENST00000312263 / NM_001349778.1; = p.R697L on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56586087; called by muse, mutect2, varscan2
- DENND4A | c.3337G>T p.D1113Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV71267131; called by muse, mutect2, varscan2
- DGLUCY | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs367885678; called by muse, mutect2, varscan2
- DHX30 | c.1141G>A p.D381N (on ENST00000445061 / NM_138615.3; = p.D342N on NM_014966.3) | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as COSV53143391; called by muse, varscan2
- DHX30 | c.1255G>C p.E419Q (on ENST00000445061 / NM_138615.3; = p.E380Q on NM_014966.3) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV53143402; called by muse, varscan2
- DHX30 | c.1309G>A p.D437N (on ENST00000445061 / NM_138615.3; = p.D398N on NM_014966.3) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.71); catalogued as COSV53143411; called by muse, varscan2
- DHX57 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV54885858, COSV54891955; called by muse, mutect2, varscan2
- DMBT1 | c.642T>G p.S214R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.113); catalogued as COSV57565125; called by muse, mutect2, varscan2
- DNAH5 | c.4563G>T p.E1521D | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV54232695, COSV54255675; called by muse, mutect2, varscan2
- DPY19L2 | c.682C>G p.P228A | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV60546215; called by muse, mutect2, varscan2
- EHBP1 | c.1104-2A>T p.X368_splice | Splice Site (SNP) | VAF 24/59 reads (41%) | catalogued as COSV99861805; called by muse, mutect2, varscan2
- EIF4B | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50409450; called by muse, mutect2, varscan2
- ERMARD | c.1099C>G p.R367G | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64648936; called by muse, mutect2, varscan2
- F11R | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV57041011; called by muse, mutect2, varscan2
- FAM47B | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV61454463; called by muse, mutect2, varscan2
- FANCA | c.1146G>T p.Q382H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66884456; called by muse, mutect2, varscan2
- FAT2 | c.9455T>G p.L3152R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55830814; called by muse, mutect2, varscan2
- FLG | c.6452G>A p.G2151E | Missense Mutation (SNP) | VAF 313/516 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs146106776, COSV64250925; called by muse, mutect2, varscan2
- FLNB | c.6745G>T p.G2249C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55897726; called by muse, mutect2, varscan2
- FOXP1 | c.1267G>T p.V423F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV59556085; called by muse, mutect2, varscan2
- GABRA6 | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50896711; called by muse, mutect2, varscan2
- GCM1 | c.863A>T p.Y288F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV52524209; called by muse, mutect2, varscan2
- GIMAP4 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV55431237, COSV99751080; called by muse, mutect2, varscan2
- GIMAP7 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57960923; called by muse, mutect2, varscan2
- GP6 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as COSV59979974; called by muse, mutect2, varscan2
- GRM8 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV58874249; called by muse, mutect2, varscan2
- GTF3C4 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 103/138 reads (75%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV64645572; called by muse, mutect2, varscan2
- HEBP1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780620747, COSV50009572; called by muse, mutect2, varscan2
- HK3 | c.2132T>A p.I711N | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52845258; called by muse, mutect2, varscan2
- HOXA13 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV56083138; called by muse, mutect2, varscan2
- INMT | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50000467, COSV50002990; called by muse, mutect2, varscan2
- KDM5B | c.729A>G p.I243M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as COSV52513863; called by muse, mutect2, varscan2
- KIFAP3 | c.179G>T p.S60I | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV63037789; called by muse, mutect2, varscan2
- KLF11 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV59941773; called by muse, mutect2, varscan2
- KRT37 | c.669C>A p.D223E | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56660319; called by muse, mutect2, varscan2
- KRTAP19-5 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as COSV61858437, COSV61859736; called by muse, mutect2, varscan2
- LAMB1 | c.1333T>C p.Y445H | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV55970866; called by muse, mutect2, varscan2
- LRRC4C | c.1193C>A p.A398E | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV53439179; called by muse, mutect2, varscan2
- LRRCC1 | c.1022A>C p.K341T | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV64484080, COSV64486159; called by muse, mutect2, varscan2
- MAGI3 | c.2062A>G p.M688V | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs1251026162, COSV56845042; called by muse, mutect2, varscan2
- MAP3K3 | c.1385C>A p.T462K | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV51992800; called by muse, mutect2, varscan2
- MED27 | c.801G>T p.M267I | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV52606957; called by muse, mutect2, varscan2
- MFN2 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV52425892; called by muse, mutect2, varscan2
- MUC17 | c.1978G>T p.V660L | Missense Mutation (SNP) | VAF 96/610 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as rs769898425, COSV60293646; called by muse, mutect2, varscan2
- MUC6 | c.2867G>C p.G956A | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV70151007; called by muse, mutect2, varscan2
- MYH13 | c.4970C>T p.S1657F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.222); catalogued as COSV52844615; called by muse, mutect2
- MYO1G | c.1021A>T p.K341* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV51857357; called by muse, mutect2, varscan2
- MYOC | c.432C>A p.N144K | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as COSV50680064; called by muse, mutect2, varscan2
- NAP1L2 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65173145; called by muse, mutect2, varscan2
- NLRP7 | c.22T>A p.W8R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV60182644; called by muse, mutect2, varscan2
- OR2D3 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53495308; called by muse, mutect2, varscan2
- OR4C16 | c.571T>A p.Y191N | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58944552; called by muse, mutect2, varscan2
- PACSIN3 | c.675A>T p.E225D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV54068119; called by muse, mutect2, varscan2
- PAK1 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | catalogued as rs769471788, COSV53702017; called by muse, mutect2, varscan2
- PAPPA2 | c.2630C>A p.S877* | Nonsense Mutation (SNP) | VAF 101/158 reads (64%) | catalogued as COSV62787765; called by muse, mutect2, varscan2
- PAX6 | c.314G>T p.R105I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746448834, COSV53795866; called by muse, mutect2, varscan2
- PCDHB10 | c.2095G>T p.V699L | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53379480, COSV53381191; called by muse, mutect2, varscan2
- PCDHB9 | c.2089G>T p.V697L | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs781806912, COSV53384428; called by muse, mutect2, varscan2
- PCDHGB7 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54044199; called by mutect2, varscan2
- PCNX2 | c.2062G>T p.G688W | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50792519, COSV50918175; called by muse, mutect2, varscan2
- PCSK5 | c.4922G>T p.S1641I | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV70453184; called by muse, mutect2, varscan2
- PHF21B | c.656C>A p.S219* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as COSV57562851; called by muse, mutect2, varscan2
- PKLR | c.71C>A p.A24E | Missense Mutation (SNP) | VAF 75/118 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV61362669; called by muse, mutect2, varscan2
- PRDM9 | c.763C>A p.Q255K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV57003733, COSV57008674; called by muse, mutect2, varscan2
- PSAP | c.634G>C p.V212L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs770498314, COSV67551310; called by muse, mutect2, varscan2
- PTPRB | c.160T>C p.W54R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as COSV51749431; called by muse, mutect2, varscan2
- RABGGTA | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs760099634, COSV53772039; called by muse, mutect2, varscan2
- REG3G | c.441del p.S148Afs*9 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as COSV55449888; called by pindel, varscan2
- REG3G | c.451A>G p.R151G | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV55448268; called by muse, varscan2
- RHOH | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101110372, COSV67805168; called by muse, mutect2, varscan2
- ROBO1 | c.3220G>T p.A1074S | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV71398930; called by muse, mutect2, varscan2
- RTN1 | c.1019C>G p.P340R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99956767; called by muse, mutect2, varscan2
- RTN1 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV99956769; called by muse, mutect2, varscan2
- SFTPA1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64867869; called by muse, mutect2, varscan2
- SIGLEC9 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.83); catalogued as COSV51588925; called by muse, mutect2, varscan2
- SIRPG | c.500C>A p.T167N | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV53810563; called by muse, mutect2, varscan2
- SLC12A1 | c.2096A>T p.D699V | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV66800380; called by muse, mutect2, varscan2
- SLC44A5 | c.1431C>A p.C477* | Nonsense Mutation (SNP) | VAF 20/148 reads (14%) | catalogued as COSV63775591; called by muse, mutect2, varscan2
- SLC4A7 | c.2383A>T p.R795* | Nonsense Mutation (SNP) | VAF 57/108 reads (53%) | catalogued as COSV55403440; called by muse, mutect2, varscan2
- SLITRK1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV65674164, COSV65674366; called by muse, varscan2
- SLITRK1 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs202070945, COSV65676480; called by muse, varscan2
- SMAD4 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1064793270, COSV61695550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNCA | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61137307; called by muse, mutect2, varscan2
- SNCB | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59434360, COSV59434720; called by muse, mutect2, varscan2
- SOX30 | c.563C>A p.A188E | Missense Mutation (SNP) | VAF 84/143 reads (59%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.213); catalogued as rs1465236088, COSV53937377, COSV53939850; called by muse, mutect2, varscan2
- SPTBN4 | c.2621G>T p.R874L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as COSV100150084, COSV58960047; called by muse, mutect2, varscan2
- STK11 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CD982957, CM134909, COSV58819919, COSV58827618; called by muse, mutect2, varscan2
- TAS2R9 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as COSV53690991; called by muse, mutect2, varscan2
- TASOR2 | c.5089G>T p.G1697C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60169873; called by muse, mutect2, varscan2
- TDRD3 | c.1385A>G p.N462S | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV52164854; called by muse, mutect2, varscan2
- TLL1 | c.918G>T p.R306S | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50331446; called by muse, mutect2, varscan2
- TNFSF14 | c.716T>C p.M239T | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55591914; called by muse, mutect2, varscan2
- TUT4 | c.2041A>T p.R681W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57120315; called by muse, mutect2, varscan2
- TXLNB | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64444034, COSV64445882; called by muse, mutect2, varscan2
- TYRP1 | c.389G>T p.R130M | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66358072; called by muse, mutect2, varscan2
- UMODL1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV68578339; called by muse, mutect2, varscan2
- USH2A | c.7819G>T p.G2607* | Nonsense Mutation (SNP) | VAF 64/102 reads (63%) | catalogued as COSV56434695, COSV56446709; called by muse, mutect2, varscan2
- VN1R4 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.292); catalogued as COSV60805094, COSV60805804; called by muse, mutect2, varscan2
- XRN1 | c.1806del p.W602Cfs*21 | Frame Shift Del (DEL) | VAF 31/59 reads (53%) | catalogued as COSV53817791; called by mutect2, pindel, varscan2
- ZFYVE26 | c.474G>T p.W158C | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV61334092; called by muse, mutect2, varscan2
- ZMAT3 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1460705234, COSV60992537, COSV60994346; called by muse, mutect2, varscan2
- ZNF14 | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as COSV59851757; called by muse, mutect2, varscan2
- ZNF521 | c.2923A>G p.T975A | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.995); catalogued as COSV64132395; called by muse, mutect2, varscan2
- ZNF560 | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 30/50 reads (60%) | catalogued as COSV56872156; called by muse, mutect2, varscan2
- ZNF653 | c.1675G>C p.E559Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53405015; called by muse, mutect2, varscan2
- ZNF816 | c.63+1G>T p.X21_splice | Splice Site (SNP) | VAF 37/113 reads (33%) | catalogued as COSV99554699; called by muse, mutect2, varscan2
- ZNF816 | c.63G>T p.Q21H | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99554701; called by muse, mutect2, varscan2
- IGKV3D-15 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.436); called by muse, varscan2
- KANSL1 | c.1290del p.R431Dfs*49 | Frame Shift Del (DEL) | VAF 37/151 reads (25%) | called by mutect2, pindel, varscan2
- KIR2DL1 | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 132/379 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- PHF24 | c.556del p.H186Tfs*33 | Frame Shift Del (DEL) | VAF 21/43 reads (49%) | called by mutect2, pindel, varscan2
- SLIT1 | c.2268del p.K757Rfs*35 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- TRAV8-4 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF331 | c.829_840del p.G277_F280del | In Frame Del (DEL) | VAF 24/70 reads (34%) | called by mutect2, pindel, varscan2
- ZNF592 | c.2755del p.R919Efs*60 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- ANO6 | c.264A>C p.T88= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV57668740; called by muse, mutect2, varscan2
- CASQ1 | c.1099C>T p.L367= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV63623536; called by muse, mutect2, varscan2
- CNGA3 | c.1317G>T p.R439= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV55628675; called by muse, mutect2, varscan2
- CXCL1 | c.162C>T p.P54= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as rs1328022334, COSV67611925; called by muse, mutect2, varscan2
- EHBP1 | c.150G>A p.R50= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV50441611; called by muse, mutect2, varscan2
- FES | c.2277C>T p.S759= | Silent (SNP) | VAF 97/254 reads (38%) | catalogued as rs776193183, COSV61001759; called by muse, mutect2, varscan2
- FGFR2 | c.798C>T p.A266= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV60661523; called by muse, varscan2
- FLRT2 | c.726G>C p.L242= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV58142216, COSV58151200; called by muse, mutect2, varscan2
- FNBP1L | c.1554C>T p.P518= (on ENST00000271234 / NM_001164473.2; = p.P460= on NM_017737.5) | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV53096932, COSV99555153; called by muse, mutect2, varscan2
- GDF6 | c.1149C>T p.C383= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1262040814, COSV54628204; called by muse, mutect2, varscan2
- GGA3 | c.186G>A p.A62= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs751018627, COSV55457274, COSV99822036; called by muse, mutect2, varscan2
- H3C2 | c.270G>A p.V90= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs1013064543, COSV52519222, COSV52520123; called by muse, mutect2, varscan2
- HPSE2 | c.882G>T p.R294= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs202038196, COSV65203087; called by muse, mutect2, varscan2
- HYDIN | c.6894T>A p.R2298= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV59272430; called by muse, mutect2, varscan2
- IGSF8 | c.1731G>A p.L577= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV58759320; called by muse, mutect2
- KCNC2 | c.297C>G p.G99= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV54381305; called by muse, mutect2, varscan2
- KCNJ3 | c.1368C>T p.T456= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV54545644; called by muse, mutect2, varscan2
- KHSRP | c.468G>T p.V156= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV67920514; called by muse, mutect2, varscan2
- LILRB4 | c.441G>A p.R147= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV54406046, COSV54409030; called by muse, varscan2
- MKI67 | c.7596C>A p.I2532= | Silent (SNP) | VAF 79/199 reads (40%) | catalogued as COSV64077375; called by muse, mutect2, varscan2
- MYH4 | c.1329C>T p.V443= | Silent (SNP) | VAF 84/266 reads (32%) | catalogued as COSV55127356; called by muse, mutect2, varscan2
- OR2M5 | c.66C>A p.P22= | Silent (SNP) | VAF 255/427 reads (60%) | catalogued as COSV63547146; called by muse, mutect2, varscan2
- PPP6R2 | c.171G>A p.L57= | Silent (SNP) | VAF 24/149 reads (16%) | catalogued as COSV53299302; called by muse, mutect2, varscan2
- PRAMEF20 | c.972C>A p.T324= | Silent (SNP) | VAF 74/432 reads (17%) | called by muse, mutect2, varscan2
- RFX6 | c.1998A>C p.P666= | Silent (SNP) | VAF 66/111 reads (59%) | catalogued as COSV60589144; called by muse, mutect2, varscan2
- SIGLEC14 | c.1104T>G p.A368= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV55784495; called by muse, mutect2, varscan2
- SMG8 | c.1374G>A p.V458= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as COSV56287353; called by muse, mutect2, varscan2
- SPTA1 | c.378C>T p.H126= | Silent (SNP) | VAF 88/144 reads (61%) | catalogued as rs774042837, COSV63760546; called by muse, mutect2, varscan2
- TECRL | c.375A>T p.A125= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV67091015; called by muse, mutect2, varscan2
- TTK | c.27A>G p.R9= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV57887123; called by muse, mutect2, varscan2
- XDH | c.1149C>T p.V383= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV65151419; called by muse, mutect2, varscan2
- AC244258.1 | n.916C>A | RNA (SNP) | VAF 59/156 reads (38%) | called by muse, mutect2, varscan2
- CTBP1 | chr4:1250790 A>G | 5'Flank (SNP) | VAF 22/55 reads (40%) | catalogued as rs1216288181; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185069G>T | Intron (SNP) | VAF 41/100 reads (41%) | catalogued as COSV100303518; called by muse, mutect2, varscan2
